TARGET case TARGET-30-PAIVMJ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/166d0ac3-9914-56b7-b2b1-3d0723f8da7a

Demographics
Sex at birth: male; Race: white; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Classification of tumor: primary; Age at diagnosis: 0.6 years (202 days); Year of diagnosis: 1999; Days to last follow up: 2,359 days (6.5 years); Cog neuroblastoma risk group: Low Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 1; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Necrosis percent: 0; Percent tumor nuclei: 100.
   Treatment given: Protocol identifier: 9047.

Follow-up (1 entry)
- Days to follow up: 2,359 days (6.5 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,359; Year of follow up: 2005.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAIVMJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAIVMJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 2359
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.7
- Histology: Favorable
- Percent Necrosis: 0
- Percent Tumor v/s Stroma: 90/10
